Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AABV, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AABV-01A (Primary Tumor).

[page 1 of 3]
Surgery date: Surgical Pathology

DIAGNOSIS:

A. Lymph nodes, common hepatic artery, biopsy: Multiple (3) lymph nodes are negative for tumor.

B. Pancreas, neck margin, excision: Low-grade pancreatic intraepithelial neoplasia (PanIN) is present. Negative for malignancy.

C. Common hepatic duct, margin, excision: Negative for tumor.

D. Lymph node, hepatic hilar, biopsy: A single (1) lymph node is negative for tumor.

E. Head of pancreas, duodenum, portion of jejunum and gallbladder, common bile duct, Whipple resection: Invasive grade 3 (of 4) ductal adenocarcinoma, is identified forming a solid mass (3.3 x 3.2 x 2.6 cm) located in the pancreatic head. The tumor extends beyond the pancreas involving the peripancreatic soft tissue and duodenal submucosa. Gallbladder shows mild chronic cholecystitis. Angiolymphatic invasion is present. Perineural invasion is present. Tumor necrosis is absent. All surgical resection margins are negative for tumor (minimum free margin, 1.2 cm, uncinate margin). Carcinoma in situ (low-grade PanIN) is present at the pancreatic margin. The adjacent non-neoplastic pancreatic parenchyma contains low-grade PanIN. Multiple (2 of 24) regional lymph nodes are positive for metastatic adenocarcinoma.

ICD-O-3
Adenocarcinoma duct NPS
Site: Pancreas head 8500/3
C25.0
JW 5/5/14

With available surgical material, [AJCC pT3N1] (7th edition, 2010).

Frozen section histologic interpretation of common hepatic artery lymph nodes performed by:

This final pathology report is based on the gross/macrosopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "common hepatic artery lymph nodes" is a 3.0 x 2.2 x 0.8 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted. Grossed by

[page 2 of 3]
B. Received fresh labeled "pancreatic neck margin" is a 2.9 x 1.9 x 0.7 cm portion of pancreatic parenchyma with orientation. All submitted. Grossed by

C. Received fresh labeled "common hepatic duct margin" is a 1.0 x 0.8 x 0.5 cm portion of tan-red tubular tissue with orientation. Margin submitted. Grossed by

D. Received fresh labeled "hepatic hilar lymph nodes" is a 2.5 x 1.7 x 1.1 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted. Grossed by

E. Received fresh labeled "head of pancreas, duodenum, portion jejunum, common bile duct, gallbladder" is a Whipple specimen consisting of 35.0 cm in length portion of duodenum, 6.1 x 4.2 x 4.0 cm portion of pancreas, 10.1 x 4.3 x 1.1 cm gallbladder. The pancreatic uncinate margin is inked yellow and shaved, the portal vein groove margin is inked black and submitted perpendicularly. There is a 3.3 x 3.2 x 2.6 cm diffusely infiltrative mass within the head of the pancreas, 1.2 cm from the uncinate margin. The mass grossly extends into the small bowel wall over an area of 8.5 cm, involving the ampulla, and into the surrounding soft tissue. A stent is present within the main pancreatic duct. The gallbladder contains no choleliths. Peripancreatic lymph nodes and periduodenal lymph nodes are identified. Representative sections are submitted. Grossed by

BLOCK SUMMARY:

Part A: Common hepatic artery lymph nodes

- 1 Com hepatic artery LN2(A1)
- 2 Com hepatic artery LN1(A2)

Part B: Pancreatic neck margin

- 1 Pancreatic neck margin1
- 2 Pancreatic neck margin2

Part C: Common hepatic duct margin

- 1 Comm hepatic duct margin

Part D: Hepatic hilar lymph node

- 1 Hepatic hilar LN (D1)

Part E: Head of pancreas, doudenum, portion jejunum, common bile duct, gallbladder

- 1 Uncinate margin 1
- 2 Uncinate margin 1
- 3 Uncinate margin 2
- 4 Uncinate margin 2
- 5 Uncinate margin 3

[page 3 of 3]
- 6 Uncinate margin 3
- 7 Mass to bowel
- 8 Ampulla
- 9 Mass to bile duct
- 10 PVG margin
- 11 Mass to surrounding St.
- 12 Mass 1
- 13 Gallbladder
- 14 Peripancreatic LN2(E1)
- 15 Peripancreatic LN5(E2)
- 16 Peripancreatic LN3(E3)
- 17 Peripancreatic LN1(E4)
- 18 Peripancreatic LN1/2(E4)
- 19 Peripancreatic LN2/2(E4)
- 20 Peripancreatic LN 3 (E6)
- 21 Peripancreatic LN 2 (E7)
- 22 Peripancreatic LN 3 (E8)
- 23 Periduodenal LN 5 (E9)

Source: NCI Genomic Data Commons file 673d5a99-2732-44d8-854f-82ae78429ce0 (TCGA-2J-AABV.D506891E-7B4D-449C-8BA9-2F8FE36C94DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).